Surgical pathology report (de-identified scan), TCGA case TCGA-WZ-A7V3, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site  International Genomics Consortium, specimen TCGA-WZ-A7V3-01A (Primary Tumor).

[page 1 of 2]
Results

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

Final Report

DIAGNOSIS

TESTIS, RIGHT, RADICAL ORCHIECTOMY:

1. Seminoma, classic type with the following characteristics:

- a. Tumor confined to testis (pT1)
- b. Surgical resection margins free of tumor
- c. Associated intratubular germ cell neoplasia

2. Surgical resection margins free of tumor

3. See testis cancer staging parameters

COMMENT

discussed these results with

reviewed this case.

*****2010 TESTIS CANCER STAGING PARAMETERS*****

Case number: Patient name:

Final TNM: pT1NXM0

2010 stage: I

MACROSCOPIC

SPECIMEN TYPE

Radical Orchiectomy

TUMOR LATERALITY

Right

TUMOR SIZE

4.2 X 2.7 X 2.7 cm

TUMOR FOCALITY

Unifocal

MICROSCOPIC

HISTOLOGIC TYPE

Seminoma, classic type

MARGINS

Spermatic cord: Uninvolved by tumor

MICROSCOPIC TUMOR EXTENSION

Tumor is limited to testis

LYMPHATIC/VASCULAR INVASION

Absent

PATHOLOGIC STAGING

EXTENT OF INVASION

pT1. (Tumor limited to the testis and epididymis without vascular/lymphatic invasion; tumor may invade into the tunica albuginea but not the tunica vaginalis)

REGIONAL LYMPH NODES

PNX. (Regional lymph nodes cannot be assessed)

ICD-O-3

Seminoma NOS 9061/3

Site ^{ccr} Testis NOS C62.9

path ^{ccr} Testicle NOS C62.9

9/10/4/13

[page 2 of 2]
DISTANT METASTASIS

pM0. (No distant metastasis)

SERUM TUMOR MARKERS

SX. (Serum marker studies not available or performed [Although LDH, HCG, and AFP values may be available, the 'S' designation in AJCC staging specifically refers to post-orchietomy levels. These levels are currently not available])

PATHOLOGIC STAGE Summary

Final TNM: pT1NXM0

2010 stage: I

* The pathologic stage presumes no lymph node metastasis.

** The pathologic stage presumes no distant metastasis.

Attending Pathologist: [REDACTED]

Reviewed by: [REDACTED]

CLINICAL INFORMATION

Right testicular mass

SPECIMEN/GROSS DESCRIPTION

SOURCE: Right testicle tumor

Received fresh labeled "right testicle" is a 5.5 x 4 x 3.2 cm testis with an attached 10 cm in length x 1.6 cm in diameter spermatic cord. The tunica vaginalis is intact. The outer surface of the testis is inked blue.

The testis is bivalved revealing a heterogeneous, 4.2 x 2.7 x 2.7 cm tumor mass. One-third of the tumor is soft, friable, tan-pink with the remainder being solid tan-pink. The surrounding normal parenchyma of the testis is unremarkable. The tumor mass is 11 cm from the spermatic cord resection margin, approaches the tunica albuginea but does not extend through it and does not appear to involve the 5 x 1 x 1 cm epididymis.

Representative portion of both portions of tumor are submitted on one chuck for frozen section diagnosis.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Germ cell tumor with non-seminomatous component." is rendered by [REDACTED]

Tissue is taken for possible ancillary study.

Representative sections are submitted in 15 cassettes as follows:

1. Frozen section of tumor
- 2-5. Representative soft friable tumor to albuginea and vaginalis and adjacent normal parenchyma
6. Solid tumor and vaginalis
7. Solid and soft tumor and normal parenchyma and albuginea
- 8-12. Random tumor
13. Mid spermatic cord
14. Epididymis, remote from tumor
15. Spermatic cord margin

This case is accessioned in

Gross dictation by: [REDACTED]

MICROSCOPIC

The microscopic appearance substantiates the diagnosis.

Dictation by: [REDACTED] transcribed by: [REDACTED]

Dual/Synchronous Primary	NOTED	DISQUALIFIED

Source: NCI Genomic Data Commons file 76a8e36b-4922-4cfe-b1e2-2e61ed85e7e3 (TCGA-WZ-A7V3.FE931927-B82F-4B8F-9392-A284DE7DBF09.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).